Somatic mutation profile of tumor specimen TARGET-15-SJMPAL017973-09A.2 (aliquot TARGET-15-SJMPAL017973-09A.2-01D) from TARGET case TARGET-15-SJMPAL017973, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,657 days).
Specimen TARGET-15-SJMPAL017973-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2515b649-1b14-46ea-aa73-fa91817c59e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL017973-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL017973-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29b994cb-7519-4136-9742-683f4564e369

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOCK2 | c.337C>A p.R113S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.137); catalogued as rs1455670567; called by muse, mutect2
- DRC7 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs979729729, COSV61053104; called by muse, mutect2, varscan2
- GPRASP1 | c.2874G>C p.E958D | Missense Mutation (SNP) | VAF 66/68 reads (97%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV100850916; called by muse, mutect2, varscan2
- RUNX1 | c.511G>A p.D171N (on ENST00000344691 / NM_001001890.3; = p.D198N on NM_001754.5) | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as CM013280, CM1515470, COSV55868860, COSV55892672; called by muse, mutect2, varscan2
- SMPD4 | c.1711G>T p.V571F (on ENST00000409031 / NM_017951.4; = p.V542F on NM_017751.4) | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60082566; called by muse, mutect2
- FKBP5 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); called by muse, mutect2
- HECW2 | c.1811G>T p.G604V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.33); called by muse, mutect2
- IFT74 | c.15C>A p.H5Q | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.019); called by muse, mutect2
- LRRC14 | c.511C>A p.L171M | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAGI2 | c.2613G>T p.E871D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.119); called by muse, mutect2
- NOX5 | c.982C>A p.H328N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NSD2 | c.2322C>A p.N774K | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2
- NXT2 | c.126C>A p.D42E (on ENST00000372106 / NM_001242617.2; = p.D97E on NM_018698.5) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.077); called by muse, mutect2
- SPDL1 | c.943C>A p.Q315K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SWT1 | c.166-17_166-8delinsAAATGATAGACTTTTTTTTTTAA p.X56_splice | Splice Site (INS) | VAF 5/36 reads (14%) | called by pindel, varscan2*
- THBS1 | c.1317C>A p.S439R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, varscan2
- CNKSR1 | c.990C>T p.N330= (on ENST00000374253 / NM_001297647.2; = p.N323= on NM_006314.3) | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as rs1325038196, COSV64162807; called by muse, mutect2, varscan2
- GRIN2A | c.1035C>A p.G345= | Silent (SNP) | VAF 22/268 reads (8%) | called by muse, mutect2
- HEY2 | c.906C>T p.A302= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as rs1322056557; called by muse, mutect2, varscan2
- TMEM132D | c.1002C>T p.G334= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs943908670, COSV70603216; called by muse, mutect2, varscan2
- VPS13C | c.8451A>G p.Q2817= (on ENST00000644861 / NM_020821.3; = p.Q2774= on NM_017684.5) | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- PCDHGA3 | c.2425-67104C>T | Intron (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
